TARGET case TARGET-00-NAAENJ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/f11fa345-a9df-40ec-a3aa-393654dbcf0a

Biospecimens (1 sample)
- Sample TARGET-00-NAAENJ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.
